Somatic mutation profile of tumor specimen 0DMOX8 from CCDI case PBCACC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.0 years (1,107 days).
Specimen 0DMOX8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1758813c-4005-4716-a7c0-329b075f07b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMOXK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24a3d6e0-8bfc-4db5-b11c-ac695aebe7c7

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX60L | c.2567G>A p.R856H | Missense Mutation (SNP) | VAF 98/1097 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs184974934; called by muse, mutect2
- ZNF845 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1239350099, COSV72004794; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 28/1072 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ST6GALNAC1 | c.1541G>A p.W514* | Nonsense Mutation (SNP) | VAF 48/584 reads (8%) | called by muse, mutect2
- WDR47 | c.2279C>T p.A760V (on ENST00000369962 / NM_001142551.2; = p.A761V on NM_014969.5) | Missense Mutation (SNP) | VAF 26/748 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2
- TMC3 | c.177T>C p.D59= | Silent (SNP) | VAF 119/557 reads (21%) | called by muse, mutect2, varscan2
- COL6A2 | c.1053+35C>T | Intron (SNP) | VAF 29/298 reads (10%) | called by muse, mutect2
- DSC1 | c.2488-222A>C | Intron (SNP) | VAF 22/105 reads (21%) | called by muse, mutect2, varscan2
